Gene-level copy-number profile of tumor specimen TCGA-3B-A9HR-01A from TCGA case TCGA-3B-A9HR, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Leiomyosarcoma, NOS; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 38.4 years (14,041 days).
Specimen TCGA-3B-A9HR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.71811cfc-2ce8-4774-947f-8bb0d312de0b.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-3B-A9HR-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/4b80c72e-6c0e-4a2f-b4e2-8ca573d194e6

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 11; copy number 1: 886; copy number 2: 13,555; copy number 3: 20,010; copy number 4: 15,462; copy number 5: 7,978; copy number 6: 1,205; copy number 9: 35; copy number 15: 210; copy number 16: 175; copy number 17: 107; copy number 18: 137; copy number 20: 40.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-3B-A9HR-01A-11D-A386-01): tumor purity 0.96, ploidy 3.21, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 11 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:46,109,621–46,537,864, 11 genes (within-gene range 0–1): AGAP7P, ANTXRLP1, ANTXRL, AGAP14P, FAM25BP, AC244230.1, ANXA8L1, AC244230.2, LINC00842, HNRNPA1P33, NPY4R.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 704 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:105,366,909–125,916,384, 347 genes, copy number 15–18 (within-gene range 4–18) (broad region; genes not listed).
- chr17:8,247,618–18,736,118, 322 genes, copy number 16–20 (broad region; genes not listed).
- chr17:21,614,487–22,706,703, 35 genes, copy number 9 (within-gene range 2–9): AC233702.1, AC233702.4, AC233702.9, KCNJ18, AC243725.1, ABBA01006766.1, NCOR1P2, UBBP4, FTLP13, LINC02002, AC138761.1, AC138761.2, FAM27E5, AC087575.1, FLJ36000, AC132825.3, AC132825.4, MTND6P35, MTCYBP13, MTRNR2L1, AC132825.2, MTND1P15, MTND2P13, AC132825.1, NMTRS-TGA3-1, MTATP6P3, MTCO3P13, AC132825.6, AC132825.7, AC132825.5, AC131055.2, AC131055.1, AC131274.3, AC131274.1, AC131274.2.

Autosomal genes at a single copy (total copy number 1): 886. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
